Somatic mutation profile of tumor specimen TCGA-VN-A943-01A (aliquot TCGA-VN-A943-01A-11D-A41K-08) from TCGA case TCGA-VN-A943, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.6 years (26,162 days).
Specimen TCGA-VN-A943-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ca49f33-2da9-4325-b1a9-30f12e092fc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VN-A943-10A (Blood Derived Normal), aliquot TCGA-VN-A943-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/934a3a6b-6ebf-4958-9a1a-b1a51eb7ebf3

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 11, Silent 5, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APTX | c.974T>G p.L325R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100541386; called by muse, mutect2, varscan2
- CRYBB2 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV101236741; called by muse, mutect2, varscan2
- FLNB | c.2575+1G>C p.X859_splice | Splice Site (SNP) | VAF 5/17 reads (29%) | catalogued as COSV55893160, COSV99913586; called by muse, mutect2, varscan2
- LSAMP | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs1399307120, COSV61294319; called by muse, mutect2, varscan2
- PPARD | c.1078+1G>T p.X360_splice | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as rs1193610079, COSV100283156; called by muse, mutect2, varscan2
- PTCHD4 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs779224258, COSV59794644; called by mutect2, varscan2
- RETREG3 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99518980; called by muse, mutect2
- REV1 | c.3085C>A p.Q1029K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99177340; called by muse, mutect2, varscan2
- RYR2 | c.12535G>A p.E4179K | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); catalogued as rs867488053, COSV63684869; called by muse, mutect2
- SCN1A | c.4958C>T p.A1653V (on ENST00000303395 / NM_001202435.3; = p.A1642V on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM113349, COSV100320816; called by muse, mutect2, varscan2
- SHROOM4 | c.1430C>A p.T477N | Missense Mutation (SNP) | VAF 60/65 reads (92%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99173642; called by muse, mutect2, varscan2
- TTI1 | c.632C>G p.P211R | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100989648; called by muse, mutect2
- USP44 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99311908; called by muse, mutect2, varscan2
- AGO3 | c.816T>C p.H272= | Silent (SNP) | VAF 4/78 reads (5%) | catalogued as COSV99868813; called by muse, mutect2
- MFSD12 | c.345C>T p.C115= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs765056797, COSV62598054; called by muse, mutect2, varscan2
- NCOR2 | c.5683C>T p.L1895= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as rs753066848, COSV62301630; called by muse, mutect2, varscan2
- NOTCH4 | c.1656C>T p.I552= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs1310022272, COSV66680016; called by muse, mutect2, varscan2
- SPOCK3 | c.702G>A p.L234= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV100693174; called by muse, mutect2, varscan2
